Somatic mutation profile of cancer-model specimen HCM-WCMC-0675-C67-85R (3D Organoid, passage 15; aliquot HCM-WCMC-0675-C67-85R-01D-A83U-36), derived from the recurrence tumor of HCMI case HCM-WCMC-0675-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage X; Tumor grade: GX; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-WCMC-0675-C67-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 15.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 594c0dfc-25fb-48ba-8f50-c63b201f38ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0675-C67-10A (Blood Derived Normal), aliquot HCM-WCMC-0675-C67-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea82df94-e300-4d0e-b778-27f62f0449ad

The open-access MAF lists 153 somatic variants for this specimen: 105 protein-altering or splice-affecting, 39 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 39, Intron 8, Nonsense Mutation 5, Frame Shift Del 4, In Frame Del 2, Frame Shift Ins 2, 3'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11A1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 151/573 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs121912811, CS021747, COSV51433766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 756/757 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 376/598 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60788908, COSV60805381; called by muse, mutect2, varscan2
- ANKRD30A | c.2664G>T p.K888N (on ENST00000611781; = p.K832N on NM_052997.2) | Missense Mutation (SNP) | VAF 23/495 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs766046581, COSV64603887; called by muse, mutect2
- APH1B | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 218/392 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1285108399; called by muse, mutect2, varscan2
- BCLAF3 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 170/366 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.127); catalogued as rs751543626, COSV61413804; called by muse, mutect2, varscan2
- BRINP3 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 357/449 reads (80%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.202); catalogued as COSV100818385, COSV66540992; called by muse, mutect2, varscan2
- CACNA1B | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 147/673 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53154562; called by muse, mutect2, varscan2
- CACNA1E | c.6676C>T p.R2226C (on ENST00000367573 / NM_001205293.3; = p.R2183C on NM_000721.4) | Missense Mutation (SNP) | VAF 211/1115 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs746785304, COSV100705332, COSV100705796; called by muse, mutect2, varscan2
- CCDC168 | c.3228del p.K1076Nfs*14 | Frame Shift Del (DEL) | VAF 60/264 reads (23%) | catalogued as rs765903699; called by mutect2, varscan2
- CDH10 | c.2191G>C p.D731H | Missense Mutation (SNP) | VAF 21/818 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52571652; called by muse, mutect2
- CYFIP1 | c.2588G>A p.R863Q | Missense Mutation (SNP) | VAF 101/328 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs770002354; called by muse, mutect2, varscan2
- DCAF15 | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 120/712 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.961); catalogued as rs1448841032; called by muse, mutect2, varscan2
- DNMBP | c.4126C>T p.R1376C | Missense Mutation (SNP) | VAF 354/695 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375209058; called by muse, mutect2, varscan2
- EGF | c.2528A>G p.Y843C | Missense Mutation (SNP) | VAF 207/315 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs1212404748, COSV54480924; called by muse, mutect2, varscan2
- ELL | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 49/386 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs190373181; called by muse, mutect2, varscan2
- ERICH3 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 117/363 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV58620295; called by muse, mutect2, varscan2
- FBN1 | c.3455C>T p.A1152V | Missense Mutation (SNP) | VAF 125/314 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs539103389, CM096445, COSV57323932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMPD2 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 40/606 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370193041; called by muse, mutect2
- HMCN1 | c.13969G>A p.E4657K | Missense Mutation (SNP) | VAF 42/792 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1183965155, COSV54890148; called by muse, mutect2
- HPR | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 122/408 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201688913; called by muse, mutect2, varscan2
- IGFALS | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 89/813 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs940549283, COSV99236297; called by muse, mutect2, varscan2
- KCP | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 169/775 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as rs981064215; called by muse, mutect2, varscan2
- KIF5A | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 200/737 reads (27%) | catalogued as COSV99672986; called by muse, mutect2, varscan2
- KLB | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 138/768 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs567666148, COSV99962575; called by muse, mutect2, varscan2
- MAG | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 239/701 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs756136921, COSV62698782; called by muse, mutect2, varscan2
- MZF1 | c.2203T>G p.*735Eext*42 | Nonstop Mutation (SNP) | VAF 11/281 reads (4%) | catalogued as rs1180839605; called by muse, mutect2
- PCDH15 | c.4996G>A p.A1666T (on ENST00000644397 / NM_001354429.2; = p.A1608T on NM_001142771.2) | Missense Mutation (SNP) | VAF 262/557 reads (47%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV100902198; called by muse, mutect2, varscan2
- PHF21B | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 444/914 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs1355672081, COSV100503463, COSV57559322; called by muse, mutect2, varscan2
- PLXNB2 | c.3532G>A p.G1178S | Missense Mutation (SNP) | VAF 168/724 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs745854880; called by muse, varscan2
- PLXND1 | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 263/415 reads (63%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.803); catalogued as rs775659642, COSV100139940; called by muse, mutect2, varscan2
- POLG | c.3646G>A p.E1216K | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1469896894; called by muse, mutect2, varscan2
- PRDM4 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 209/675 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs757375674, COSV57307145; called by muse, mutect2, varscan2
- PROKR2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 136/676 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146544539; ClinVar: likely benign; called by muse, varscan2
- RIMKLA | c.1136_1138del p.N379del | In Frame Del (DEL) | VAF 107/364 reads (29%) | catalogued as rs1360884924; called by pindel, varscan2
- RYR2 | c.7706T>C p.I2569T | Missense Mutation (SNP) | VAF 327/407 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as rs761497764, COSV63685387; called by muse, mutect2, varscan2
- RYR2 | c.10265A>G p.Q3422R | Missense Mutation (SNP) | VAF 153/215 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV63724073; called by muse, mutect2, varscan2
- SEC24B | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 64/433 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.122); catalogued as COSV54508310; called by muse, mutect2, varscan2
- SEMA6C | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 98/469 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1412160295; called by muse, mutect2, varscan2
- SLC4A11 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 31/1114 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs984393831, COSV66261349; called by muse, mutect2
- SOX8 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 84/1115 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs555677616; called by muse, mutect2
- TNN | c.3827C>T p.P1276L | Missense Mutation (SNP) | VAF 139/802 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747233076; called by muse, mutect2, varscan2
- TSC1 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 453/454 reads (100%) | catalogued as COSV99036974; called by muse, mutect2, varscan2
- TSHZ2 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 262/1240 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs757806984, COSV61589633; called by muse, mutect2, varscan2
- TTN | c.34813C>T p.P11605S (on ENST00000591111; = p.P10678S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/302 reads (27%) | PolyPhen benign (0); catalogued as rs1560102675; called by muse, mutect2, varscan2
- UTP3 | c.1249A>G p.K417E | Missense Mutation (SNP) | VAF 193/298 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191703808; called by muse, mutect2, varscan2
- ZNF274 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1432256836; called by muse, mutect2, varscan2
- ZNF707 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 79/1052 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1443490506, COSV100690545; called by muse, mutect2
- ADCY10 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 87/537 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO4 | c.263C>T p.S88L (on ENST00000392977 / NM_001286615.2; = p.S53L on NM_178826.4) | Missense Mutation (SNP) | VAF 189/575 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP27 | c.2191_2207del p.L731Kfs*11 (on ENST00000428638 / NM_001282290.1; = p.L390Kfs*11 on NM_199282.3) | Frame Shift Del (DEL) | VAF 79/681 reads (12%) | called by mutect2, pindel
- C3orf84 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 154/462 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CA13 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 253/428 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPF | c.5983C>G p.Q1995E | Missense Mutation (SNP) | VAF 156/777 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNOT11 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 85/281 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUZD1 | c.1466G>A p.R489K | Missense Mutation (SNP) | VAF 137/662 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CWF19L2 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 129/560 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DCLK3 | c.436_437dup p.E147Gfs*33 | Frame Shift Ins (INS) | VAF 139/516 reads (27%) | called by mutect2, varscan2
- DCSTAMP | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 104/580 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DNAJC2 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 58/620 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- DNER | c.558_560del p.V187del | In Frame Del (DEL) | VAF 35/206 reads (17%) | called by mutect2, pindel, varscan2
- EIF4B | c.1348A>G p.T450A | Missense Mutation (SNP) | VAF 170/387 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ERBB2 | c.696dup p.T233Hfs*2 | Frame Shift Ins (INS) | VAF 217/955 reads (23%) | called by mutect2, pindel, varscan2
- ESYT3 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 131/441 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM83C | c.2045T>C p.L682P | Missense Mutation (SNP) | VAF 164/920 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLRT3 | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 97/481 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GFOD2 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 153/490 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- HMCN1 | c.5073A>T p.E1691D | Missense Mutation (SNP) | VAF 145/831 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HPX | c.973C>A p.Q325K | Missense Mutation (SNP) | VAF 131/245 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- IGKV2D-24 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 254/403 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- IMPDH2 | c.549A>T p.E183D | Missense Mutation (SNP) | VAF 79/318 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IQGAP1 | c.1813G>C p.E605Q | Missense Mutation (SNP) | VAF 79/372 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KALRN | c.7033G>C p.G2345R (on ENST00000360013 / NM_001024660.4; = p.G648R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/618 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDR | c.3085C>A p.L1029M | Missense Mutation (SNP) | VAF 105/335 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF18A | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF5A | c.1622G>A p.G541E | Missense Mutation (SNP) | VAF 248/919 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIFAP3 | c.2333A>G p.Y778C | Missense Mutation (SNP) | VAF 48/593 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- KLK15 | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 669/670 reads (100%) | called by muse, mutect2
- KLKB1 | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 97/163 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KNL1 | c.3517G>T p.A1173S (on ENST00000346991 / NM_170589.5; = p.A1147S on NM_144508.5) | Missense Mutation (SNP) | VAF 187/495 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- LAMA3 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 97/206 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRFN5 | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 234/235 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP3K10 | c.1598G>C p.G533A | Missense Mutation (SNP) | VAF 413/604 reads (68%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MUC16 | c.6598C>A p.P2200T | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- NECTIN1 | c.1492G>T p.A498S | Missense Mutation (SNP) | VAF 168/730 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, varscan2
- NRK | c.4007T>C p.I1336T | Missense Mutation (SNP) | VAF 184/185 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- OR2T4 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 104/1208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR8B3 | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 209/451 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARD3 | c.2695G>T p.E899* | Nonsense Mutation (SNP) | VAF 212/495 reads (43%) | called by muse, mutect2
- PHF11 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 183/369 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PPARG | c.1169A>G p.D390G (on ENST00000287820 / NM_015869.5; = p.D360G on NM_005037.7) | Missense Mutation (SNP) | VAF 178/522 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- PRKCE | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 377/544 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PSME4 | c.3484A>C p.K1162Q | Missense Mutation (SNP) | VAF 181/258 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- RANBP9 | c.1217A>T p.N406I | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SBNO2 | c.3479G>A p.R1160Q | Missense Mutation (SNP) | VAF 177/962 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCMH1 | c.1421del p.S474Yfs*5 (on ENST00000326197 / NM_001031694.2; = p.S427Yfs*5 on NM_012236.4) | Frame Shift Del (DEL) | VAF 132/482 reads (27%) | called by mutect2, pindel, varscan2
- SEMA3G | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 197/663 reads (30%) | called by muse, mutect2, varscan2
- SNCAIP | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 126/403 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM53 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 70/557 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOPAZ1 | c.427A>T p.T143S | Missense Mutation (SNP) | VAF 146/444 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- UGT3A2 | c.850_854del p.E284Lfs*71 | Frame Shift Del (DEL) | VAF 74/679 reads (11%) | called by mutect2, pindel
- ZC3HAV1 | c.2257A>C p.N753H | Missense Mutation (SNP) | VAF 66/398 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- ZCCHC24 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 340/702 reads (48%) | SIFT tolerated, low confidence (0.68); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ZNF214 | c.681T>G p.I227M | Missense Mutation (SNP) | VAF 128/237 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF579 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 32/1209 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2
- AKR1B15 | c.996C>T p.F332= | Silent (SNP) | VAF 124/329 reads (38%) | called by muse, mutect2, varscan2
- AMFR | c.189G>A p.P63= | Silent (SNP) | VAF 559/870 reads (64%) | catalogued as rs1402738438, COSV51921384; called by muse, mutect2, varscan2
- ARHGEF18 | c.474C>G p.T158= (on ENST00000359920 / NM_001130955.2; = p.T54= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/314 reads (35%) | called by muse, mutect2, varscan2
- C2CD2L | c.171G>A p.A57= | Silent (SNP) | VAF 769/1003 reads (77%) | catalogued as rs565781414; called by muse, mutect2, varscan2
- CC2D2B | c.2364C>T p.A788= | Silent (SNP) | VAF 120/237 reads (51%) | called by muse, mutect2, varscan2
- CDHR3 | c.690C>T p.N230= | Silent (SNP) | VAF 254/549 reads (46%) | catalogued as rs368294260; called by muse, mutect2, varscan2
- COL5A1 | c.1896C>T p.F632= | Silent (SNP) | VAF 141/515 reads (27%) | catalogued as rs376478864; ClinVar: conflicting interpretations of pathogenicity / benign; called by muse, mutect2, varscan2
- DCUN1D4 | c.600G>T p.A200= | Silent (SNP) | VAF 39/171 reads (23%) | called by mutect2, varscan2
- DDX39A | c.1275G>A p.Q425= | Silent (SNP) | VAF 310/492 reads (63%) | called by muse, mutect2, varscan2
- EFCC1 | c.1359G>T p.L453= | Silent (SNP) | VAF 132/488 reads (27%) | called by muse, mutect2, varscan2
- FBXL7 | c.1284C>T p.F428= | Silent (SNP) | VAF 78/1140 reads (7%) | called by muse, mutect2
- GAK | c.3724C>T p.L1242= | Silent (SNP) | VAF 228/851 reads (27%) | catalogued as rs1480840279; called by muse, mutect2, varscan2
- GALNT9 | c.918G>A p.P306= | Silent (SNP) | VAF 161/900 reads (18%) | catalogued as rs938904169, COSV61101484; called by muse, mutect2, varscan2
- GDF6 | c.1353G>A p.S451= | Silent (SNP) | VAF 16/492 reads (3%) | catalogued as COSV54626982; called by muse, mutect2
- GPR180 | c.708G>A p.G236= | Silent (SNP) | VAF 59/359 reads (16%) | catalogued as rs768458574; called by muse, mutect2, varscan2
- H2BC21 | c.288G>A p.Q96= | Silent (SNP) | VAF 113/656 reads (17%) | called by muse, mutect2, varscan2
- HCN4 | c.324C>A p.G108= | Silent (SNP) | VAF 566/994 reads (57%) | catalogued as COSV56081063; called by muse, mutect2, varscan2
- HTT | c.3078T>C p.C1026= | Silent (SNP) | VAF 339/462 reads (73%) | called by muse, mutect2, varscan2
- KCNF1 | c.1255C>T p.L419= | Silent (SNP) | VAF 349/567 reads (62%) | called by muse, mutect2, varscan2
- KIAA1755 | c.1911C>T p.D637= | Silent (SNP) | VAF 139/818 reads (17%) | catalogued as rs112826952; called by muse, mutect2, varscan2
- KL | c.234C>T p.G78= | Silent (SNP) | VAF 235/985 reads (24%) | called by muse, mutect2, varscan2
- MAG | c.213G>A p.P71= | Silent (SNP) | VAF 40/776 reads (5%) | catalogued as rs199750254, COSV62699502; called by muse, mutect2
- NIT2 | c.240C>T p.L80= | Silent (SNP) | VAF 77/222 reads (35%) | called by muse, mutect2, varscan2
- NR2E3 | c.729C>T p.S243= | Silent (SNP) | VAF 131/365 reads (36%) | catalogued as rs747947987, COSV58909507; called by muse, mutect2, varscan2
- PANX2 | c.1914G>A p.E638= | Silent (SNP) | VAF 402/845 reads (48%) | catalogued as rs1025554683; called by muse, mutect2, varscan2
- PCDHB10 | c.1770G>A p.V590= | Silent (SNP) | VAF 180/984 reads (18%) | catalogued as rs1554284375; called by muse, mutect2
- PCDHB9 | c.1770G>A p.V590= | Silent (SNP) | VAF 477/678 reads (70%) | called by muse, mutect2, varscan2
- RAPSN | c.6G>A p.G2= | Silent (SNP) | VAF 114/242 reads (47%) | catalogued as rs201291481; called by muse, mutect2, varscan2
- SAMD9 | c.1797T>C p.D599= | Silent (SNP) | VAF 28/394 reads (7%) | called by muse, mutect2
- SCARB1 | c.1572G>A p.T524= | Silent (SNP) | VAF 122/1720 reads (7%) | catalogued as rs917254342; called by muse, mutect2
- SCYL3 | c.1032G>A p.Q344= | Silent (SNP) | VAF 160/902 reads (18%) | called by muse, mutect2, varscan2
- SEMA3G | c.2055G>T p.P685= | Silent (SNP) | VAF 196/661 reads (30%) | catalogued as COSV51594006; called by muse, mutect2, varscan2
- SLC28A3 | c.648A>G p.L216= | Silent (SNP) | VAF 113/221 reads (51%) | catalogued as rs762486318; called by muse, mutect2, varscan2
- SPATA7 | c.618A>G p.T206= | Silent (SNP) | VAF 487/488 reads (100%) | catalogued as rs576385745; called by muse, mutect2, varscan2
- SYCE1L | c.6G>A p.A2= | Silent (SNP) | VAF 126/375 reads (34%) | catalogued as rs908248831; called by muse, mutect2, varscan2
- WARS2 | c.885G>A p.A295= | Silent (SNP) | VAF 396/594 reads (67%) | catalogued as rs946355135, COSV52477659; called by muse, mutect2, varscan2
- ZFC3H1 | c.528G>A p.L176= | Silent (SNP) | VAF 418/1172 reads (36%) | called by muse, mutect2, varscan2
- ZIC5 | c.120G>A p.A40= | Silent (SNP) | VAF 247/1057 reads (23%) | catalogued as rs1228981414; called by muse, mutect2, varscan2
- ZNF865 | c.2316C>T p.D772= | Silent (SNP) | VAF 108/1266 reads (9%) | catalogued as rs1432221105; called by muse, mutect2
- APOB | c.2436+80C>T | Intron (SNP) | VAF 142/501 reads (28%) | catalogued as rs749924496; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+27121C>T | Intron (SNP) | VAF 17/294 reads (6%) | catalogued as rs1266154424; called by muse, mutect2
- MIR4435-2HG | n.161-61979C>G | Intron (SNP) | VAF 91/384 reads (24%) | catalogued as rs996073812; called by muse, mutect2
- SDF4 | c.892-89A>G | Intron (SNP) | VAF 332/530 reads (63%) | catalogued as rs576116710; called by muse, mutect2, varscan2
- SH2B3 | c.733-11808C>T | Intron (SNP) | VAF 142/1019 reads (14%) | called by muse, mutect2, varscan2
- TMTC3 | c.*2794A>G | 3'UTR (SNP) | VAF 158/488 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.10361-4267A>G | Intron (SNP) | VAF 112/321 reads (35%) | called by muse, mutect2, varscan2
- TTN | c.10361-4850C>A | Intron (SNP) | VAF 72/279 reads (26%) | called by muse, mutect2, varscan2
- UNC13B | c.762-7136G>A | Intron (SNP) | VAF 169/365 reads (46%) | called by muse, mutect2, varscan2
